Somatic mutation profile of tumor specimen TCGA-DX-A6BG-01A (aliquot TCGA-DX-A6BG-01A-11D-A307-09) from TCGA case TCGA-DX-A6BG, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 51.1 years (18,682 days).
Specimen TCGA-DX-A6BG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9168f084-4d50-4be0-8ffb-527f533542dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6BG-10A (Blood Derived Normal), aliquot TCGA-DX-A6BG-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/100794a3-ae34-4109-ac2a-95f7dca5f87a

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRD3 | c.1795A>G p.I599V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100324923; called by muse, mutect2
- EXOSC7 | c.629A>T p.H210L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.169); catalogued as COSV99651944; called by muse, mutect2, varscan2
- FREM2 | c.3579G>A p.M1193I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1480750584, COSV99748249; called by muse, mutect2, varscan2
- IL1RAPL1 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100146651; called by muse, mutect2
- NF1 | c.3510C>G p.H1170Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100646649; called by muse, mutect2
- PROZ | c.1096T>C p.F366L | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100720309; called by muse, mutect2, varscan2
- TTC8 | c.1355A>T p.N452I (on ENST00000338104 / NM_001288781.1; = p.N436I on NM_144596.4) | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100581244, COSV57626595; called by muse, mutect2, varscan2
- ZNF521 | c.3400G>C p.G1134R | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.187); catalogued as rs757758786, COSV100831859; called by muse, mutect2, varscan2
- ZNF710 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1273138183, COSV99184120; called by muse, mutect2, varscan2
- ERICH3 | c.1172del p.S391Yfs*34 | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | called by mutect2, pindel, varscan2
- HNF1B | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2
- WNK2 | c.3880_3892del p.S1294Pfs*38 | Frame Shift Del (DEL) | VAF 27/184 reads (15%) | called by mutect2, pindel, varscan2
- FLG | c.1320C>T p.H440= | Silent (SNP) | VAF 24/323 reads (7%) | catalogued as rs376019219; called by muse, mutect2
- GSTA4 | c.255C>T p.N85= | Silent (SNP) | VAF 16/209 reads (8%) | catalogued as COSV100919830; called by muse, mutect2
- ORC2 | c.195A>G p.L65= | Silent (SNP) | VAF 4/95 reads (4%) | catalogued as COSV99309496; called by muse, mutect2
- SHTN1 | c.963A>G p.E321= | Silent (SNP) | VAF 25/207 reads (12%) | catalogued as COSV99598757; called by muse, mutect2, varscan2
- STX16 | c.51C>T p.S17= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs147707535; called by muse, mutect2, varscan2
- MRPS17P9 | n.223A>G | RNA (SNP) | VAF 6/36 reads (17%) | called by muse, varscan2
